Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAEZ, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAEZ-01A (Primary Tumor).

Department of Pathology

ICD O-3
Seminoma NOS 9061/3
Site @ Testis NOS C62.9
J1 3/3/14

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 6 cm; no angio-invasion present; tumor confined to testis in available slides; no invasion in rete testis.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Reviewer Initials	J1	Date Reviewed: 1/18/14

Source: NCI Genomic Data Commons file 1ffe0602-38d1-47c1-828c-0add6838a02c (TCGA-2G-AAEZ-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).